Gene-level copy-number profile of tumor specimen HTMCP-02-03-01010-01B from CGCI case HTMCP-02-03-01010, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage II; Age at diagnosis: 40.2 years (14,672 days).
Specimen HTMCP-02-03-01010-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fda989e6-7208-4da0-ac5d-b53be0d66b61.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-03-01010-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/6e2193d9-1887-43f5-8b1e-c552f0ecc89d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 10; copy number 2: 12,013; copy number 3: 12,961; copy number 4: 25,912; copy number 5: 5,035; copy number 6: 1,488; copy number 7: 184; copy number 8: 46; copy number 9: 1,034; copy number 10: 49; copy number 11: 103; copy number 14: 53.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:49,923,049–49,923,886, 1 gene: OR4R3P.
- chr19:186,373–474,983, 13 genes: SEPTIN14P19, CICP19, LINC01002, RNU6-1076P, PLPP2, MIER2, AC016588.1, THEG, AC010641.1, C2CD4C, SHC2, RNA5SP462, ODF3L2.
- chr19:54,224,523–54,230,213, 2 genes (within-gene range 0–3): AC245052.7, AC245052.3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,239 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:100,826,820–145,010,993, 884 genes, copy number 9–11 (within-gene range 7–11) (broad region; genes not listed).
- chr7:148,438,309–152,855,378, 143 genes, copy number 9–10 (broad region; genes not listed).
- chr7:153,887,097–154,894,285, 1 gene, copy number 9 (within-gene range 8–9): DPP6.
- chr7:154,055,286–154,063,325, 1 gene, copy number 9 (within-gene range 8–9): AC006019.1.
- chr7:154,544,169–159,233,377, 80 genes, copy number 9 (broad region; genes not listed).
- chr9:33,441,156–35,815,354, 130 genes, copy number 9–14 (within-gene range 2–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
